Somatic mutation profile of tumor specimen TARGET-10-PAPDUV-09A (aliquot TARGET-10-PAPDUV-09A-01D) from TARGET case TARGET-10-PAPDUV, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.4 years (1,986 days).
Specimen TARGET-10-PAPDUV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dad815de-e24b-4f2b-8b57-39e45cea10bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPDUV-10A (Blood Derived Normal), aliquot TARGET-10-PAPDUV-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33080908-c406-40bd-bafb-893104bdd679

The open-access MAF lists 17 somatic variants for this specimen: 16 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 11, Nonsense Mutation 2, Frame Shift Ins 1, Frame Shift Del 1, In Frame Ins 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1526G>C p.G509A (on ENST00000288602 / NM_001374244.1; = p.G469A on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs121913355, CM060876, COSV56061424, COSV56062352, COSV56065622; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CSF3R | c.1853C>T p.T618I | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs796065343, COSV58963463; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AHNAK2 | c.10805C>T p.P3602L | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as rs745713300; called by muse, mutect2, varscan2
- BSND | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.998); catalogued as rs781639127; called by muse, mutect2, varscan2
- CRIM1 | c.462T>G p.F154L | Missense Mutation (SNP) | VAF 97/195 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as rs1338067142, COSV54864805; called by muse, mutect2, varscan2
- DGCR2 | c.1102G>A p.V368I | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.99); catalogued as COSV54218694; called by muse, mutect2, varscan2
- GPC5 | c.1174C>T p.R392* | Nonsense Mutation (SNP) | VAF 33/62 reads (53%) | catalogued as rs915980144; called by muse, mutect2, varscan2
- HTR1D | c.452C>T p.T151M | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371294680; called by muse, mutect2, varscan2
- PLVAP | c.910C>G p.L304V | Missense Mutation (SNP) | VAF 51/106 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as COSV53083790, COSV53085417; called by muse, mutect2, varscan2
- RIBC1 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs782595983; called by muse, mutect2, varscan2
- SHANK2 | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.458); catalogued as rs782481305, COSV58353308; called by muse, mutect2, varscan2
- ZBTB40 | c.3532C>T p.Q1178* | Nonsense Mutation (SNP) | VAF 38/90 reads (42%) | catalogued as COSV65145421; called by muse, mutect2
- COL5A2 | c.2405C>T p.P802L | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- IGHV1-69 | c.350_351insCCTGAG p.A116_R117insSL | In Frame Ins (INS) | VAF 17/45 reads (38%) | called by muse*, pindel
- KCNMA1 | c.3397del p.L1133Ffs*8 (on ENST00000286628 / NM_001161352.2; = p.L1075Ffs*8 on NM_002247.4) | Frame Shift Del (DEL) | VAF 78/182 reads (43%) | called by mutect2, pindel, varscan2
- NIPBL | c.4099dup p.S1367Kfs*8 | Frame Shift Ins (INS) | VAF 28/73 reads (38%) | called by mutect2, pindel, varscan2
- MYO15A | c.1443G>A p.P481= | Silent (SNP) | VAF 41/89 reads (46%) | catalogued as rs939958189; called by muse, mutect2, varscan2
